Somatic mutation profile of tumor specimen HTMCP-03-06-02373-01A (aliquot HTMCP-03-06-02373-01A-01D-10409) from CGCI case HTMCP-03-06-02373, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.0 years (15,699 days).
Specimen HTMCP-03-06-02373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd66250b-a8d6-4d10-8aba-9798c0827210.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02373-10A (Blood Derived Normal), aliquot HTMCP-03-06-02373-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0f6c65d-c714-4d8c-8777-d3bc248fe77e

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/166 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF9 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53641702; called by muse, mutect2, varscan2
- SGSM2 | c.2035G>A p.E679K (on ENST00000426855 / NM_001098509.2; = p.E724K on NM_014853.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs758380631; called by mutect2, varscan2
- SOX30 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53938975; called by muse, mutect2, varscan2
- SRRT | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1401412210, COSV61452563; called by muse, mutect2
- VPS53 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1161539491, COSV99346543; called by muse, mutect2, varscan2
- CDH8 | c.2372_2373del p.S791Cfs*3 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by pindel, varscan2
- EMILIN2 | c.2962_2965del p.E988Sfs*26 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.3570T>G p.F1190L | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COL5A2 | c.3279T>A p.A1093= | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- VPS13A | c.6306A>G p.P2102= | Silent (SNP) | VAF 28/295 reads (9%) | catalogued as rs774130512; called by muse, mutect2
- TUBB8B | chr18:50220 C>T | 5'Flank (SNP) | VAF 56/763 reads (7%) | catalogued as rs374037622; called by muse, mutect2
